Somatic mutation profile of tumor specimen TCGA-IM-A3U2-01A (aliquot TCGA-IM-A3U2-01A-21D-A22D-08) from TCGA case TCGA-IM-A3U2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-IM-A3U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 159f4a32-de9b-43c6-9b0e-a14c07f1c294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A3U2-10A (Blood Derived Normal), aliquot TCGA-IM-A3U2-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dfa678f-cfd6-4809-be64-63bf41250f17

The open-access MAF lists 38 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 26, Silent 5, Frame Shift Del 3, Frame Shift Ins 1, Nonsense Mutation 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AP3D1 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs753212898, COSV61425304; called by muse, mutect2, varscan2
- ARMC1 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs1010741451, COSV52535175; called by muse, mutect2, varscan2
- ASH1L | c.8728A>G p.T2910A (on ENST00000368346 / NM_001366177.2; = p.T2905A on NM_018489.3) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs760857394, COSV64215069; called by muse, mutect2, varscan2
- BNC2 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.378); catalogued as COSV66159360; called by muse, mutect2, varscan2
- COL20A1 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV58929622; called by muse, mutect2, varscan2
- CPT1C | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs548745420, COSV54923266; called by muse, mutect2, varscan2
- CPZ | c.565T>A p.S189T (on ENST00000360986 / NM_001014447.3; = p.S178T on NM_003652.3) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV59926779; called by muse, mutect2
- DEPDC5 | c.1852A>G p.M618V | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV56703961; called by muse, mutect2, varscan2
- DGAT2L6 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.946); catalogued as COSV100284206, COSV60719023; called by muse, mutect2, varscan2
- DNAH8 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778334889, COSV59487114; called by muse, mutect2, varscan2
- DNTTIP1 | c.603+1G>A p.X201_splice | Splice Site (SNP) | VAF 17/72 reads (24%) | catalogued as COSV65460774; called by muse, mutect2, varscan2
- ELOVL1 | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.216); catalogued as COSV60523351; called by muse, mutect2, varscan2
- GRB7 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV58447573, COSV58451543; called by muse, mutect2, varscan2
- HEATR1 | c.4375C>G p.Q1459E | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63983655; called by muse, mutect2, varscan2
- HNRNPUL2 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV53666956; called by muse, mutect2, varscan2
- IGSF1 | c.940A>T p.I314F | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV63841089; called by muse, mutect2
- KDM2A | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV58191880; called by muse, mutect2, varscan2
- KIAA1958 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.043); catalogued as COSV61729117; called by muse, mutect2, varscan2
- KMT5B | c.2452T>C p.Y818H | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.959); catalogued as COSV58570461; called by muse, mutect2, varscan2
- LGR5 | c.2523G>A p.W841* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs1416685198, COSV57004987, COSV57011235; called by muse, mutect2, varscan2
- MAGEB10 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.042); catalogued as COSV63313028; called by muse, mutect2
- POLR2B | c.2840T>G p.I947S | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV58903386; called by muse, mutect2, varscan2
- PRR35 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV53465608; called by muse, varscan2
- PSG8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60616774; called by muse, mutect2, varscan2
- SEPTIN6 | c.892T>G p.Y298D | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59718390; called by muse, mutect2, varscan2
- SETDB1 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 148/319 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54983839; called by muse, mutect2, varscan2
- SYTL3 | c.1292A>G p.H431R (on ENST00000611299 / NM_001242394.1; = p.H363R on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV51916224; called by muse, mutect2, varscan2
- DBH | c.1222_1265del p.A408Sfs*154 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel
- DNMT3A | c.718_731del p.E240Sfs*8 | Frame Shift Del (DEL) | VAF 25/131 reads (19%) | called by mutect2, pindel, varscan2
- MYO19 | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP6R3 | c.952del p.E318Nfs*11 (on ENST00000393800 / NM_001352375.2; = p.E318Nfs*30 on NM_018312.5) | Frame Shift Del (DEL) | VAF 41/228 reads (18%) | called by mutect2, pindel, varscan2
- PRDM1 | c.501dup p.P168Sfs*21 | Frame Shift Ins (INS) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- ATP4A | c.2421C>T p.V807= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as COSV52872748; called by muse, mutect2, varscan2
- FOXR2 | c.249C>T p.D83= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV59259984; called by muse, mutect2, varscan2
- MUC16 | c.22026A>C p.T7342= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs537879149, COSV67502556; called by muse, mutect2, varscan2
- SIGLEC1 | c.3102C>T p.P1034= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as rs551720638, COSV52469779; called by muse, mutect2, varscan2
- SLC22A2 | c.99C>T p.F33= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs568261775, COSV65268498; called by muse, mutect2, varscan2
